Somatic mutation profile of tumor specimen TCGA-46-6025-01A (aliquot TCGA-46-6025-01A-11D-1817-08) from TCGA case TCGA-46-6025, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.6 years (26,168 days).
Specimen TCGA-46-6025-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5331ffb8-4fa9-4dd7-a227-76ee2f5e7702.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-46-6025-10A (Blood Derived Normal), aliquot TCGA-46-6025-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5173624-d8f8-4089-b12d-2fe236f351ad

The open-access MAF lists 217 somatic variants for this specimen: 171 protein-altering or splice-affecting, 42 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 42, Frame Shift Del 13, Nonsense Mutation 9, In Frame Del 6, Splice Site 2, Intron 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 35/74 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691043, CM115637, COSV52672812, COSV52700410; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCF3 | c.17A>G p.E6G | Missense Mutation (SNP) | VAF 16/199 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV53047479; called by muse, mutect2
- ABCG2 | c.514A>C p.K172Q | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as COSV52944438; called by muse, mutect2, varscan2
- ABCG8 | c.755T>A p.V252E | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55391486; called by muse, mutect2, varscan2
- ADAMTS12 | c.4288G>A p.E1430K | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV61258416; called by muse, mutect2
- AHNAK | c.1658C>T p.T553I | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as rs1382243849, COSV57207752; called by muse, mutect2
- ALG6 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.378); catalogued as rs748327731, COSV54763868; called by muse, mutect2, varscan2
- AP1M1 | c.358T>C p.F120L | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV52225520; called by muse, mutect2, varscan2
- ARHGAP1 | c.274C>G p.R92G | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61734584; called by muse, mutect2, varscan2
- ARHGAP10 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs768263847, COSV60596560; called by muse, mutect2, varscan2
- ARHGEF40 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.438); catalogued as rs772697146, COSV53879019; called by muse, mutect2, varscan2
- ATG9A | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as rs771444739, COSV63445088; called by muse, mutect2, varscan2
- BAZ1B | c.2069A>T p.E690V | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59989651; called by muse, mutect2, varscan2
- BAZ1B | c.2068G>T p.E690* | Nonsense Mutation (SNP) | VAF 61/132 reads (46%) | catalogued as COSV59989661; called by muse, mutect2, varscan2
- BCLAF3 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61413453; called by muse, mutect2, varscan2
- BICRAL | c.2521C>T p.R841W | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs372362992; called by muse, mutect2, varscan2
- BMP10 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV54894497; called by muse, mutect2, varscan2
- BSDC1 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV61981597; called by muse, mutect2, varscan2
- CALCOCO1 | c.975G>T p.K325N | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.559); catalogued as COSV50412471; called by muse, mutect2, varscan2
- CCDC141 | c.2272G>A p.V758I | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.46); catalogued as COSV55370908; called by muse, mutect2, varscan2
- CCDC178 | c.613T>C p.W205R | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55765530; called by muse, mutect2, varscan2
- CCDC69 | c.883G>C p.A295P | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV62599268; called by muse, mutect2, varscan2
- CCNB3 | c.443C>G p.T148S | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV52071262; called by muse, mutect2, varscan2
- CCR1 | c.362T>A p.I121N | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV56121840; called by muse, mutect2, varscan2
- CCRL2 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368305696; called by muse, mutect2, varscan2
- CD2 | c.287A>T p.H96L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV65643420; called by muse, mutect2, varscan2
- CELSR3 | c.7217C>G p.S2406C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV50843611, COSV99375268; called by muse, mutect2, varscan2
- CERK | c.1096A>T p.K366* | Nonsense Mutation (SNP) | VAF 24/141 reads (17%) | catalogued as COSV53450502; called by muse, mutect2, varscan2
- CHD6 | c.6860G>T p.R2287L | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64689127; called by muse, mutect2, varscan2
- CNNM2 | c.915C>G p.I305M | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV63995689; called by muse, mutect2, varscan2
- CNTNAP4 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as rs1013311455, COSV56671148; called by muse, mutect2, varscan2
- COL24A1 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65303943; called by muse, mutect2, varscan2
- COL2A1 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.995); catalogued as COSV61528938; called by muse, mutect2, varscan2
- COL6A3 | c.9480G>T p.K3160N | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV55083836, COSV99802203; called by muse, mutect2, varscan2
- COP1 | c.2171C>T p.T724I | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.84); catalogued as COSV58164740; called by muse, mutect2, varscan2
- CPD | c.1699G>C p.E567Q | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56711628; called by muse, mutect2, varscan2
- CREBBP | c.2441C>T p.P814L | Missense Mutation (SNP) | VAF 61/91 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as COSV52117774; called by muse, mutect2, varscan2
- CSMD1 | c.2266G>A p.E756K (on ENST00000520002; = p.E755K on NM_033225.6) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV59298705; called by muse, mutect2, varscan2
- CUBN | c.6300A>C p.R2100S | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.591); catalogued as COSV64710904; called by muse, mutect2, varscan2
- CYP27C1 | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 69/126 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV58866451; called by muse, mutect2, varscan2
- DAP3 | c.339A>T p.K113N | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.592); catalogued as COSV58019777; called by muse, mutect2, varscan2
- DMAP1 | c.1307T>G p.I436S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV60000229; called by muse, mutect2, varscan2
- DNAH10 | c.5127G>A p.M1709I (on ENST00000409039; = p.M1648I on NM_207437.3) | Missense Mutation (SNP) | VAF 76/115 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68990249, COSV68996365; called by muse, mutect2, varscan2
- DNAH8 | c.4418del p.N1473Ifs*15 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs778628413, COSV59486260; called by mutect2, varscan2
- ECM1 | c.1144T>A p.L382M | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs375471875; called by muse, mutect2, varscan2
- EDDM3B | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV58746753; called by muse, mutect2, varscan2
- ELF4 | c.717C>G p.F239L | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57451855; called by muse, mutect2, varscan2
- ERN2 | c.2694G>C p.R898S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV55621185; called by muse, mutect2, varscan2
- FCRL4 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 167/315 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV54860901, COSV54862331; called by muse, mutect2, varscan2
- GAS2L3 | c.1909A>G p.K637E | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV57156519; called by muse, mutect2
- GCC2 | c.3829A>G p.I1277V | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV59174826; called by muse, mutect2
- GFAP | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV53649582; called by muse, mutect2, varscan2
- GRXCR1 | c.171T>A p.D57E | Missense Mutation (SNP) | VAF 132/237 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67670793; called by muse, mutect2, varscan2
- HCK | c.987C>G p.I329M | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV52941263; called by muse, mutect2, varscan2
- HEPH | c.1936C>A p.L646M (on ENST00000343002; = p.L379M on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.403); catalogued as COSV57960914; called by muse, mutect2, varscan2
- HS1BP3 | c.263C>G p.A88G | Missense Mutation (SNP) | VAF 37/333 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV58312362; called by muse, mutect2, varscan2
- HTT | c.8983A>C p.N2995H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61859259; called by muse, mutect2, varscan2
- HUWE1 | c.9169G>T p.D3057Y | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53338952; called by muse, mutect2, varscan2
- IFI27 | c.197T>C p.I66T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV54140641; called by muse, mutect2, varscan2
- IGF2R | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs919932123, COSV63627392; called by muse, mutect2, varscan2
- IGLC7 | c.104C>A p.P35Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs763740253; called by muse, mutect2, varscan2
- IMP4 | c.771G>C p.M257I | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV52091398; called by muse, mutect2, varscan2
- ITGA9 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV53238693; called by muse, mutect2, varscan2
- ITGAE | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV53991044; called by muse, mutect2, varscan2
- ITGAV | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 55/352 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53710473; called by muse, mutect2, varscan2
- ITLN2 | c.825+1G>C p.X275_splice | Splice Site (SNP) | VAF 15/95 reads (16%) | catalogued as COSV63537559; called by muse, mutect2, varscan2
- KCNU1 | c.457T>A p.F153I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67754242; called by muse, mutect2, varscan2
- KEAP1 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 40/73 reads (55%) | catalogued as COSV50267235; called by muse, mutect2, varscan2
- KIAA1210 | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.85); catalogued as COSV68176188; called by muse, mutect2, varscan2
- KIAA1549 | c.5044G>A p.E1682K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54309032; called by muse, mutect2, varscan2
- KIF14 | c.4410C>G p.I1470M | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs547122818, COSV66260583; called by muse, mutect2, varscan2
- KIF2B | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV52128279; called by muse, mutect2, varscan2
- KRT32 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV56786079; called by muse, mutect2
- LETM1 | c.1609-1G>T p.X537_splice | Splice Site (SNP) | VAF 34/123 reads (28%) | catalogued as COSV57099562; called by muse, mutect2, varscan2
- LPO | c.839C>G p.A280G | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV51857537; called by muse, mutect2, varscan2
- LTA | c.225C>G p.N75K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs756209861, COSV69304339; called by muse, mutect2, varscan2
- MAP1A | c.5147G>A p.G1716E | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.46); catalogued as COSV55807258; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV51718046; called by muse, mutect2, varscan2
- MASTL | c.113T>A p.V38E | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV58758524; called by muse, mutect2, varscan2
- MCM10 | c.1370A>G p.D457G (on ENST00000484800 / NM_182751.3; = p.D456G on NM_018518.5) | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs1444030016, COSV66333513; called by muse, mutect2, varscan2
- METTL21A | c.346A>C p.T116P | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55881344; called by muse, mutect2, varscan2
- MGAT3 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as COSV57864619; called by muse, mutect2, varscan2
- MKI67 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.936); catalogued as COSV64073410, COSV64074937; called by muse, mutect2, varscan2
- MKLN1 | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV61760298; called by muse, mutect2, varscan2
- MMP2 | c.698G>T p.C233F | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54599758, COSV99527738; called by muse, mutect2, varscan2
- MTMR3 | c.2098G>T p.E700* | Nonsense Mutation (SNP) | VAF 41/130 reads (32%) | catalogued as COSV60302667; called by muse, mutect2, varscan2
- MYLK3 | c.1377G>C p.E459D | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV67363164; called by muse, mutect2, varscan2
- NCAPD3 | c.3514G>C p.D1172H | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV73257938, COSV73258040; called by muse, mutect2, varscan2
- NELL2 | c.1621T>G p.C541G | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61571529; called by muse, mutect2, varscan2
- OCA2 | c.1235T>A p.V412E | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62341631; called by muse, mutect2, varscan2
- OR1N2 | c.931G>T p.G311* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as rs745922925, COSV65460390; called by muse, mutect2, varscan2
- OR2B3 | c.639G>T p.L213F | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.132); catalogued as COSV65850818, COSV65850822; called by muse, mutect2, varscan2
- PCDHB12 | c.1530C>G p.N510K | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as COSV53394324, COSV99507721; called by muse, mutect2, varscan2
- PGBD1 | c.840A>T p.Q280H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV99460800; called by muse, mutect2, varscan2
- PHC3 | c.2332A>G p.M778V (on ENST00000494943 / NM_001308116.2; = p.M790V on NM_024947.4) | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs750964749, COSV71948491; called by muse, mutect2
- PKD1 | c.6658C>T p.R2220W | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769509393, CM104474, COSV51912923; called by muse, mutect2, varscan2
- PPFIA4 | c.2774C>T p.T925I (on ENST00000447715; = p.T926I on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV55313012; called by muse, mutect2, varscan2
- PRKAB2 | c.424G>C p.V142L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV54212830; called by muse, mutect2, varscan2
- PSAT1 | c.607G>A p.G203S | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61302267; called by muse, mutect2, varscan2
- PSD2 | c.1673A>G p.Y558C | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs767643758, COSV51197645; called by muse, mutect2, varscan2
- PTPN11 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as COSV61006884; called by muse, mutect2, varscan2
- PXDN | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53228747; called by muse, mutect2, varscan2
- RAB3D | c.430G>T p.V144F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as COSV55791113; called by muse, mutect2, varscan2
- RASD2 | c.50A>C p.K17T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV53352182; called by muse, mutect2
- RHOC | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV53516981; called by muse, mutect2, varscan2
- RNF213 | c.6238A>G p.M2080V | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV60393310; called by muse, mutect2, varscan2
- RXFP1 | c.448C>G p.H150D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.102); catalogued as COSV57047994; called by muse, mutect2, varscan2
- SFI1 | c.2987C>G p.A996G (on ENST00000400288 / NM_001007467.3; = p.A965G on NM_014775.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.558); catalogued as COSV56716464, COSV56718121; called by muse, mutect2, varscan2
- SLC14A2 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs746382847, COSV54907444; called by muse, mutect2, varscan2
- SLC38A5 | c.1108G>C p.A370P | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58333695; called by muse, mutect2, varscan2
- SLC52A1 | c.1075C>A p.L359M | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.64); PolyPhen probably damaging (1); catalogued as COSV54692564; called by muse, mutect2, varscan2
- SLC7A1 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV66329989; called by muse, mutect2, varscan2
- SLC9C1 | c.2589A>C p.E863D | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV59886576; called by muse, mutect2, varscan2
- SLCO6A1 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 77/131 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs754259039, COSV65806843; called by muse, mutect2, varscan2
- SMC1B | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.099); catalogued as COSV62528886; called by muse, mutect2, varscan2
- SMCHD1 | c.85T>A p.Y29N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV55253518; called by muse, mutect2, varscan2
- SMPD4 | c.1093C>A p.H365N (on ENST00000409031 / NM_017951.4; = p.H336N on NM_017751.4) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60079151; called by muse, mutect2, varscan2
- SPARCL1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 156/422 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV56802839; called by muse, mutect2, varscan2
- SPATA31D1 | c.1007C>A p.S336* | Nonsense Mutation (SNP) | VAF 44/195 reads (23%) | catalogued as COSV61193909; called by muse, mutect2, varscan2
- SPDYE3 | c.1401C>G p.F467L | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.383); catalogued as COSV60106828; called by muse, mutect2, varscan2
- SSH2 | c.3362C>A p.T1121K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.036); catalogued as COSV52168507; called by muse, mutect2, varscan2
- ST3GAL1 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | PolyPhen benign (0.007); catalogued as COSV60611291; called by muse, mutect2, varscan2
- TAAR6 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV51582954; called by muse, mutect2, varscan2
- TENM1 | c.2968C>G p.P990A | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.017); catalogued as COSV64426155; called by muse, mutect2, varscan2
- TEP1 | c.5087C>A p.A1696D | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52989826; called by muse, mutect2, varscan2
- TEP1 | c.5086G>T p.A1696S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as COSV52989834; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV51510696; called by muse, mutect2, varscan2
- THBS3 | c.2116G>C p.D706H | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64248799; called by muse, mutect2, varscan2
- TIMM17A | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV66170865; called by muse, mutect2, varscan2
- TLE3 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs756815719, COSV58167632; called by muse, mutect2, varscan2
- TLN2 | c.6871A>G p.M2291V | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV60887346; called by muse, mutect2, varscan2
- TMOD3 | c.151C>G p.R51G | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57942613; called by muse, mutect2, varscan2
- TMPRSS7 | c.926C>A p.S309Y (on ENST00000452346; = p.S183Y on NM_001042575.2) | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV69980094; called by muse, mutect2, varscan2
- TNR | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as COSV54874117, COSV54876378; called by muse, mutect2, varscan2
- TRPM1 | c.2749C>T p.R917C | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370469506; called by muse, mutect2, varscan2
- TSC2 | c.2702G>A p.R901H | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1273957629, COSV54759928; called by muse, mutect2, varscan2
- TTN | c.71827G>C p.E23943Q (on ENST00000591111; = p.E16519Q on NM_003319.4) | Missense Mutation (SNP) | VAF 72/201 reads (36%) | PolyPhen possibly damaging (0.801); catalogued as COSV59949458, COSV60104540, COSV60184380; called by muse, mutect2, varscan2
- TTN | c.49571G>A p.R16524H (on ENST00000591111; = p.R9100H on NM_003319.4) | Missense Mutation (SNP) | VAF 31/136 reads (23%) | PolyPhen possibly damaging (0.669); catalogued as rs574313741, COSV59904654; called by muse, mutect2, varscan2
- UBL3 | c.26T>C p.M9T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1352333536, COSV66209178; called by muse, mutect2, varscan2
- UTP20 | c.7183G>C p.E2395Q | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55374311; called by muse, mutect2, varscan2
- VPS8 | c.1259G>C p.S420T (on ENST00000625842 / NM_001349294.1; = p.S418T on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/417 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV54982261; called by muse, mutect2
- WDR43 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.538); catalogued as COSV56098197; called by muse, mutect2, varscan2
- WIPF1 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.896); catalogued as COSV55812558; called by muse, mutect2, varscan2
- WRN | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV53297711; called by muse, mutect2, varscan2
- ZFHX4 | c.964A>G p.I322V | Missense Mutation (SNP) | VAF 64/117 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV50637553; called by muse, mutect2, varscan2
- ZFP36L2 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.059); catalogued as COSV56697423, COSV56700013; called by muse, mutect2, varscan2
- ZNF254 | c.94A>T p.I32F | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV60053764; called by muse, mutect2, varscan2
- ZNF285 | c.900C>G p.S300R | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.853); catalogued as rs1413850790, COSV58408322; called by muse, mutect2, varscan2
- ZNF585B | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV57214858; called by muse, mutect2, varscan2
- ZNF622 | c.1193G>T p.R398I | Missense Mutation (SNP) | VAF 90/168 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV58073744; called by muse, mutect2, varscan2
- ZNF774 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.907); catalogued as COSV62979809; called by muse, mutect2, varscan2
- ADAMTS15 | c.1462_1469del p.A488Hfs*95 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- CALHM1 | c.184_196del p.L62Cfs*6 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- CAMKK1 | c.1055_1068delinsA p.P352Hfs*30 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | called by pindel, varscan2*
- CAMKK2 | c.1505_1519del p.G502_E506del | In Frame Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- EEF1B2 | c.582_611del p.D195_E204del | In Frame Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, pindel
- ERI3 | c.77_99del p.A26Dfs*119 | Frame Shift Del (DEL) | VAF 3/39 reads (8%) | called by mutect2, pindel
- FAM135A | c.8_10del p.E3del | In Frame Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- FBXW12 | c.1184_1213del p.T395_Y404del | In Frame Del (DEL) | VAF 24/126 reads (19%) | called by mutect2, pindel
- FPR1 | c.649_657del p.V217_V219del | In Frame Del (DEL) | VAF 14/129 reads (11%) | called by mutect2, pindel
- HK2 | c.2384_2393del p.L795Rfs*10 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- INCENP | c.1177_1197del p.P393_N399del | In Frame Del (DEL) | VAF 22/204 reads (11%) | called by mutect2, pindel
- MUC2 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.1); called by muse, mutect2
- PRKCE | c.1316del p.L439* | Frame Shift Del (DEL) | VAF 52/159 reads (33%) | called by mutect2, pindel, varscan2
- SEMA6A | c.2451_2453delinsA p.L818Afs*10 | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | called by pindel, varscan2*
- SRMS | c.304_334del p.V102Lfs*92 | Frame Shift Del (DEL) | VAF 30/223 reads (13%) | called by mutect2, pindel
- SUGP1 | c.1625del p.K542Rfs*3 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- TDRD6 | c.5134_5162del p.I1712Vfs*5 | Frame Shift Del (DEL) | VAF 14/144 reads (10%) | called by mutect2, pindel
- USP28 | c.1896_1912del p.D632Efs*4 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | called by mutect2, pindel, varscan2
- ZNF84 | c.1697C>T p.T566I | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- ZNRF3 | c.1630_1652del p.A544Qfs*15 (on ENST00000544604 / NM_001206998.2; = p.A444Qfs*15 on NM_032173.3) | Frame Shift Del (DEL) | VAF 27/58 reads (47%) | called by mutect2, pindel, varscan2
- A2M | c.3648T>C p.Y1216= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs754842091, COSV59384260; called by muse, mutect2, varscan2
- ADGRV1 | c.9559C>T p.L3187= | Silent (SNP) | VAF 85/116 reads (73%) | catalogued as COSV67981031; called by muse, mutect2, varscan2
- ADSS1 | c.321A>G p.P107= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as rs1172351904; called by muse, mutect2
- APOB | c.10842T>G p.P3614= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV51928509; called by muse, mutect2, varscan2
- BPTF | c.1090C>T p.L364= | Silent (SNP) | VAF 31/191 reads (16%) | catalogued as COSV58833863; called by muse, mutect2, varscan2
- C1orf105 | c.48T>C p.I16= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV51129674; called by muse, mutect2, varscan2
- CD300C | c.447A>T p.S149= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as COSV58169889, COSV58170623; called by muse, mutect2, varscan2
- COG6 | c.171C>G p.L57= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as COSV62995354; called by muse, mutect2, varscan2
- DALRD3 | c.1560T>C p.L520= (on ENST00000341949 / NM_001009996.3; = p.L353= on NM_018114.5) | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV58244378; called by muse, mutect2, varscan2
- DNAH5 | c.4014C>T p.F1338= | Silent (SNP) | VAF 37/203 reads (18%) | catalogued as rs1300115173, COSV54212656; called by muse, mutect2, varscan2
- DOP1B | c.4599C>G p.S1533= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV101215805, COSV67692600; called by muse, mutect2, varscan2
- FCRL2 | c.1410G>A p.V470= | Silent (SNP) | VAF 91/201 reads (45%) | catalogued as COSV63833060; called by muse, mutect2, varscan2
- FCRL3 | c.1560C>T p.I520= | Silent (SNP) | VAF 22/204 reads (11%) | catalogued as COSV63840248; called by muse, mutect2, varscan2
- GFAP | c.315G>C p.R105= | Silent (SNP) | VAF 25/187 reads (13%) | catalogued as COSV53649601; called by muse, mutect2, varscan2
- GH2 | c.93C>T p.P31= | Silent (SNP) | VAF 40/350 reads (11%) | catalogued as rs1446943589, COSV60426187; called by muse, varscan2
- HECW1 | c.600A>G p.G200= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV67825599; called by muse, mutect2, varscan2
- HYDIN | c.5679C>T p.N1893= | Silent (SNP) | VAF 8/61 reads (13%) | called by mutect2, varscan2
- IGHM | c.852C>T p.A284= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs373090661; called by muse, mutect2, varscan2
- LPIN3 | c.1062A>T p.P354= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV64717763; called by muse, mutect2, varscan2
- LRRC17 | c.105G>C p.A35= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV50864318, COSV99978758; called by muse, mutect2, varscan2
- MACF1 | c.8214C>T p.D2738= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs755338410, COSV57112577; called by muse, mutect2, varscan2
- MAT1A | c.981G>A p.P327= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs149163315; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MRC2 | c.2835C>A p.A945= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV57637889; called by muse, mutect2, varscan2
- NAV2 | c.2928C>T p.S976= (on ENST00000396087 / NM_001244963.2; = p.S953= on NM_145117.5) | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs913323403, COSV60657578; called by muse, mutect2, varscan2
- NAV3 | c.6585A>G p.K2195= (on ENST00000397909 / NM_001024383.2; = p.K2173= on NM_014903.6) | Silent (SNP) | VAF 57/133 reads (43%) | catalogued as COSV57069057; called by muse, mutect2, varscan2
- PDIA4 | c.387C>T p.A129= | Silent (SNP) | VAF 41/69 reads (59%) | catalogued as COSV53723843; called by muse, mutect2, varscan2
- PGAP3 | c.207G>A p.K69= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV56130467; called by muse, mutect2, varscan2
- PLEKHA6 | c.2943A>C p.S981= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV55331682; called by muse, mutect2, varscan2
- PLXDC1 | c.1212A>C p.A404= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV59550149; called by muse, mutect2, varscan2
- PREP | c.267C>T p.F89= (on ENST00000369110; = p.F155= on NM_002726.5) | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV64869607; called by muse, mutect2, varscan2
- PRKD2 | c.1236G>C p.T412= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV52185308; called by muse, mutect2, varscan2
- SLC22A16 | c.1665C>T p.L555= | Silent (SNP) | VAF 82/147 reads (56%) | catalogued as COSV57928376; called by muse, mutect2, varscan2
- SLC29A1 | c.435C>A p.I145= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as COSV57577669; called by muse, mutect2, varscan2
- SLC9A3 | c.798G>T p.V266= | Silent (SNP) | VAF 53/98 reads (54%) | catalogued as COSV53799765; called by muse, mutect2, varscan2
- THOC2 | c.93C>T p.L31= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs956347436, COSV55542703; called by muse, mutect2, varscan2
- TRAV38-2DV8 | c.132A>G p.T44= | Silent (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- TRIM16L | c.825T>C p.P275= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV67459200; called by muse, mutect2, varscan2
- TRPM6 | c.3784C>T p.L1262= | Silent (SNP) | VAF 30/183 reads (16%) | catalogued as COSV62505357; called by muse, mutect2, varscan2
- TTN | c.31404C>T p.H10468= (on ENST00000591111; = p.H9541= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV59949514; called by muse, mutect2, varscan2
- UTY | c.1911T>C p.N637= | Silent (SNP) | VAF 65/149 reads (44%) | catalogued as COSV58868683; called by muse, mutect2, varscan2
- ZFYVE1 | c.1092T>C p.T364= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as rs1312295600, COSV59610334; called by muse, mutect2, varscan2
- ZNF512B | c.273G>T p.L91= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as COSV53867536; called by muse, mutect2, varscan2
- AL161729.4 | chr9:95516662 del TTCTTCTCCTCCGTTTTCTTCTTC | 3'Flank (DEL) | VAF 28/59 reads (47%) | called by mutect2, varscan2
- ATAD3C | c.*75T>C | 3'UTR (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100426586; called by muse, mutect2, varscan2
- ERCC6 | c.1397+8308G>C | Intron (SNP) | VAF 85/178 reads (48%) | catalogued as COSV63388710; called by muse, mutect2, varscan2
- GTPBP3 | c.664+41C>T | Intron (SNP) | VAF 25/103 reads (24%) | catalogued as COSV50173750; called by muse, mutect2, varscan2
